Somatic mutation profile of tumor specimen TCGA-77-8148-01A (aliquot TCGA-77-8148-01A-11D-2244-08) from TCGA case TCGA-77-8148, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.2 years (24,918 days).
Specimen TCGA-77-8148-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45c559bf-0ec8-45b5-92b6-77ee8cc49326.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8148-10A (Blood Derived Normal), aliquot TCGA-77-8148-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0744f9e9-7a27-4ffd-bb4a-7049b84106bd

The open-access MAF lists 279 somatic variants for this specimen: 206 protein-altering or splice-affecting, 63 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 63, Nonsense Mutation 15, Frame Shift Del 8, Intron 6, Splice Region 3, RNA 3, Splice Site 3, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 31/74 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV101036304, COSV66066827; called by muse, mutect2, varscan2
- ABCA6 | c.4445G>A p.R1482H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200105664, COSV99445407; called by muse, mutect2, varscan2
- ABCB11 | c.3366C>A p.S1122R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99791262; called by muse, mutect2, varscan2
- ACTL8 | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100958451, COSV64860337; called by muse, mutect2, varscan2
- ADAM2 | c.1543C>A p.L515I | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.04); catalogued as COSV99696462; called by muse, mutect2, varscan2
- ADAMTS20 | c.4620G>T p.R1540S | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV101238644; called by muse, mutect2, varscan2
- ADGRB3 | c.3005C>A p.T1002N | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99482990; called by muse, mutect2, varscan2
- AHNAK2 | c.8560G>T p.G2854W | Missense Mutation (SNP) | VAF 221/310 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100314886, COSV100319241, COSV60908726; called by muse, varscan2
- ALG11 | c.326del p.G109Vfs*5 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | catalogued as COSV73000736; called by mutect2, pindel, varscan2
- ALK | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV101200712; called by muse, mutect2, varscan2
- AMBP | c.556+1G>T p.X186_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99468655; called by muse, mutect2, varscan2
- AMY2B | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100796138; called by muse, mutect2, varscan2
- ANKRD13C | c.534G>C p.W178C | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99255993; called by muse, mutect2, varscan2
- ANKRD34B | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100103325; called by muse, mutect2, varscan2
- ARHGEF12 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 128/188 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as rs773624142, COSV100754518; called by muse, mutect2, varscan2
- ARMC4 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV59472455; called by muse, mutect2, varscan2
- ASPM | c.4749G>T p.K1583N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99659225; called by muse, mutect2, varscan2
- ASXL3 | c.1414A>G p.T472A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99322750; called by muse, mutect2
- ATAD2 | c.1810C>G p.R604G | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1404811221, COSV54877562, COSV99783859; called by muse, mutect2, varscan2
- ATP10A | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749423426, COSV100791389, COSV63513932; called by muse, mutect2, varscan2
- ATP1B2 | c.797C>G p.A266G | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100006787; called by muse, mutect2, varscan2
- ATP5PD | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1270297032, COSV100043094; called by muse, mutect2, varscan2
- BPIFA3 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.284); catalogued as rs374295673; called by muse, mutect2, varscan2
- CACNG6 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 151/249 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV53168055; called by muse, mutect2, varscan2
- CAMK2A | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1160671001, COSV62244965, COSV62245410; called by muse, mutect2
- CBLN2 | c.200T>A p.V67E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99504034; called by muse, mutect2, varscan2
- CD163 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100775567; called by muse, mutect2
- CENPE | c.6612G>C p.K2204N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99476645; called by muse, mutect2, varscan2
- CEP192 | c.5755G>A p.G1919S | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100380364; called by muse, mutect2, varscan2
- CEP68 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 118/265 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.104); catalogued as COSV53124484, COSV99560360; called by muse, mutect2, varscan2
- CHD8 | c.4348G>C p.E1450Q (on ENST00000646647 / NM_001170629.2; = p.E1171Q on NM_020920.4) | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV100783763; called by muse, mutect2
- CHRM2 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 107/232 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280427; called by muse, mutect2, varscan2
- CHRM3 | c.1268G>C p.S423T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as COSV99697108; called by muse, mutect2, varscan2
- CHRNB3 | c.1316T>C p.V439A | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV99250773; called by muse, mutect2, varscan2
- CNGA4 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.619); catalogued as COSV99791573; called by muse, mutect2, varscan2
- CNTN1 | c.551A>C p.D184A | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100750746; called by muse, mutect2
- CNTN6 | c.1086G>A p.E362= | Splice Region (SNP) | VAF 20/31 reads (65%) | catalogued as COSV100609560; called by muse, mutect2, varscan2
- COL22A1 | c.101G>T p.S34I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100275431; called by muse, mutect2
- COL9A1 | c.1700C>A p.A567E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.563); catalogued as COSV100293591; called by muse, mutect2, varscan2
- CSMD1 | c.3167G>T p.R1056L (on ENST00000520002; = p.R1055L on NM_033225.6) | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.996); catalogued as COSV59310950, COSV59395021; called by muse, mutect2, varscan2
- CUEDC2 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.694); catalogued as rs778175495, COSV50045262; called by muse, mutect2, varscan2
- CYBB | c.1138T>C p.W380R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.384); catalogued as COSV101059661; called by muse, mutect2, varscan2
- CYP11B1 | c.547A>T p.S183C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99454269; called by muse, mutect2, varscan2
- CYP2A6 | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99991677; called by muse, mutect2, varscan2
- DCLRE1A | c.2767G>A p.D923N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as rs145559640; called by muse, mutect2, varscan2
- DENND1A | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101010298, COSV65325294; called by muse, mutect2, varscan2
- DHX15 | c.849A>T p.R283S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391031; called by muse, mutect2, varscan2
- DMXL2 | c.7226C>T p.S2409F | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV99195899; called by muse, mutect2, varscan2
- DNAH11 | c.7538G>T p.G2513V | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100176058; called by muse, mutect2, varscan2
- DNAH2 | c.5063C>T p.S1688L | Missense Mutation (SNP) | VAF 12/420 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV101208911; called by muse, mutect2
- DNAH5 | c.4301G>A p.W1434* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV54220439, COSV99443108; called by muse, mutect2, varscan2
- DPPA4 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as COSV100169118; called by muse, mutect2, varscan2
- DSTYK | c.1781A>G p.N594S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as rs1469321397, COSV100904402; called by muse, mutect2, varscan2
- DUSP10 | c.1287G>A p.M429I | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV100099964; called by muse, mutect2, varscan2
- DYNC1H1 | c.3631A>G p.I1211V | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100794146; called by muse, mutect2, varscan2
- ECE1 | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1316358496, COSV51665239; called by muse, mutect2
- ENPP1 | c.2362A>G p.R788G | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100719285; called by muse, mutect2, varscan2
- ENPP1 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV100719287; called by muse, mutect2, varscan2
- EPHA5 | c.2881C>A p.P961T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV99894873; called by muse, mutect2, varscan2
- EPHA5 | c.2357C>A p.A786E | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV56649453; called by muse, mutect2, varscan2
- EPHB3 | c.410C>G p.A137G | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV100382694; called by muse, mutect2, varscan2
- ERMAP | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs150664549; called by muse, mutect2
- ESPL1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs142300200, COSV99228650; called by muse, mutect2, varscan2
- FAM83B | c.743G>T p.W248L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100173859; called by muse, mutect2, varscan2
- FBXO38 | c.2788G>A p.V930I (on ENST00000340253 / NM_205836.3; = p.V855I on NM_030793.5) | Missense Mutation (SNP) | VAF 73/105 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99692989; called by muse, mutect2, varscan2
- FCRL3 | c.766G>T p.G256W | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100942687; called by muse, mutect2, varscan2
- FNIP1 | c.2773A>T p.I925F | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV100330154; called by muse, mutect2, varscan2
- FOXN3 | c.1366G>A p.A456T (on ENST00000261302; = p.A434T on NM_005197.4) | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV54307813; called by muse, mutect2, varscan2
- FSCB | c.2425G>T p.E809* | Nonsense Mutation (SNP) | VAF 4/70 reads (6%) | catalogued as COSV100468698, COSV61217529; called by muse, mutect2
- FUT8 | c.1483G>A p.D495N (on ENST00000360689 / NM_001371534.1; = p.D332N on NM_004480.4) | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61293181; called by muse, mutect2, varscan2
- FUT9 | c.266A>T p.Q89L | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100132779; called by muse, mutect2, varscan2
- GALNT9 | c.1234G>A p.V412M (on ENST00000328957 / NM_001122636.2; = p.V46M on NM_021808.3) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774144284, COSV100200864; called by muse, mutect2, varscan2
- GBP3 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 59/85 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99352273; called by muse, mutect2, varscan2
- GEMIN2 | c.565-2del p.X189_splice | Splice Site (DEL) | VAF 17/56 reads (30%) | catalogued as rs778407936; called by mutect2, pindel, varscan2
- GRXCR1 | c.341G>T p.S114I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV101295572; called by muse, mutect2, varscan2
- GTF2H4 | c.1244A>T p.Q415L | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV99461311; called by muse, mutect2, varscan2
- GTF3A | c.589T>C p.F197L | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV100820173; called by muse, mutect2, varscan2
- HERC2 | c.3775G>C p.V1259L | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.682); catalogued as COSV99869751; called by muse, mutect2, varscan2
- HFE | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as COSV100352480; called by muse, mutect2
- HPS5 | c.2036C>T p.S679L (on ENST00000349215 / NM_181507.2; = p.S565L on NM_007216.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs779921624, COSV100752213, COSV61688057; called by muse, mutect2, varscan2
- HS3ST5 | c.953C>G p.P318R | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV100450028; called by muse, mutect2, varscan2
- IGF2BP1 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 93/237 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV99288091; called by muse, mutect2, varscan2
- IGKV2D-29 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101534349; called by muse, mutect2, varscan2
- IRF8 | c.583T>A p.Y195N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.332); catalogued as COSV99235929; called by muse, mutect2, varscan2
- ITGA4 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs758516673, COSV52002097; called by muse, mutect2
- ITGA9 | c.741G>C p.L247= | Splice Region (SNP) | VAF 13/22 reads (59%) | catalogued as COSV99291174; called by muse, mutect2, varscan2
- ITPA | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs777033296, COSV66318319; called by muse, mutect2
- KBTBD7 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.433); catalogued as COSV101067981; called by muse, mutect2, varscan2
- KCTD8 | c.1047del p.T350Lfs*38 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as COSV63590665; called by mutect2, pindel, varscan2
- KMT2C | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 34/922 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51460080, COSV51516738; called by muse, mutect2
- LARP4B | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1275544682, COSV60221173; called by muse, mutect2, varscan2
- LEMD3 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 32/98 reads (33%) | catalogued as COSV100384112; called by muse, mutect2, varscan2
- LILRA1 | c.864C>A p.S288R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs770333122; called by muse, mutect2
- LIPE | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs141471711; called by muse, mutect2, varscan2
- MAGEB16 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as COSV101303294, COSV67873820, COSV67874582; called by muse, mutect2, varscan2
- MAGEB6 | c.274A>T p.K92* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100983627; called by muse, mutect2
- MANBA | c.2583T>A p.F861L (on ENST00000642252; = p.F815L on NM_005908.4) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.839); catalogued as COSV99898152; called by muse, mutect2, varscan2
- MIB2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs924091482, COSV100598618; called by muse, mutect2, varscan2
- MNDA | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.405); catalogued as COSV100933216; called by muse, mutect2, varscan2
- MON1B | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220762371, COSV50248906; called by muse, mutect2, varscan2
- MSC | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57697375; called by muse, mutect2
- MTMR12 | c.1439T>C p.L480S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99373262; called by muse, mutect2, varscan2
- MUC17 | c.12458G>A p.W4153* | Nonsense Mutation (SNP) | VAF 54/117 reads (46%) | catalogued as COSV100071016; called by muse, mutect2, varscan2
- MYBPC1 | c.3080C>A p.A1027D (on ENST00000550270 / NM_206820.2; = p.A1034D on NM_002465.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV100637668; called by muse, mutect2, varscan2
- MYO6 | c.588G>T p.K196N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100889209; called by muse, mutect2, varscan2
- MYORG | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.495); catalogued as COSV99898218; called by muse, mutect2, varscan2
- NBEA | c.6956T>C p.V2319A | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100075564; called by muse, mutect2, varscan2
- NEIL3 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV99219844; called by muse, mutect2, varscan2
- NELL1 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as rs1180556024, COSV54237631; called by muse, mutect2, varscan2
- NETO1 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100197965; called by muse, mutect2, varscan2
- NIPSNAP2 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 230/375 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100436602; called by muse, mutect2, varscan2
- NKD1 | c.1190T>C p.L397P | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99193983; called by muse, mutect2, varscan2
- NPY2R | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV100279356; called by muse, mutect2, varscan2
- NRCAM | c.2183G>C p.G728A (on ENST00000379028 / NM_001371124.1; = p.G712A on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100694062; called by muse, mutect2, varscan2
- OR10G7 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 94/152 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1480229259, COSV100389941, COSV57866127; called by muse, mutect2, varscan2
- OR12D3 | c.359G>C p.R120P | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs200720757, COSV101011043; called by muse, mutect2, varscan2
- OR2L8 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100593971; called by muse, mutect2, varscan2
- OR4A15 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV59038207; called by muse, mutect2, varscan2
- OR4C11 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV100155077; called by muse, mutect2, varscan2
- OR51E2 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); catalogued as COSV101211286; called by muse, mutect2, varscan2
- OR6T1 | c.727T>A p.S243T | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100189627; called by muse, mutect2, varscan2
- OR8K5 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV57888238; called by muse, mutect2, varscan2
- PABPC5 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100442025; called by muse, mutect2, varscan2
- PARPBP | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100568908; called by muse, mutect2
- PCDH11X | c.3493C>T p.Q1165* | Nonsense Mutation (SNP) | VAF 47/66 reads (71%) | catalogued as COSV100006837; called by muse, mutect2, varscan2
- PCDH8 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs932516611, COSV100131053, COSV100132077; called by muse, mutect2, varscan2
- PCDHB1 | c.596C>G p.P199R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV100127980, COSV60633722; called by muse, mutect2, varscan2
- PCDHB16 | c.221A>G p.H74R | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.015); catalogued as COSV99500662; called by muse, mutect2, varscan2
- PDK4 | c.433T>C p.C145R | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs538664118, COSV99138699; called by muse, mutect2, varscan2
- PGC | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV100756806; called by muse, mutect2, varscan2
- PHACTR3 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV63025484; called by muse, mutect2, varscan2
- PIK3C2B | c.4045C>T p.R1349W | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs1362684590, COSV65812291; called by muse, mutect2, varscan2
- PLCL1 | c.1827T>G p.Y609* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as COSV101406729; called by muse, mutect2, varscan2
- PLEKHG2 | c.4034G>T p.G1345V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99216586; called by muse, mutect2, varscan2
- POLR2B | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as rs371226484; called by muse, varscan2
- POSTN | c.2269G>T p.G757C | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV101123190; called by muse, mutect2, varscan2
- PPP4R4 | c.1585A>T p.R529* | Nonsense Mutation (SNP) | VAF 82/143 reads (57%) | catalogued as COSV100428140; called by muse, mutect2, varscan2
- PRSS12 | c.2401C>G p.R801G | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV99627468; called by muse, mutect2, varscan2
- PTPN13 | c.6706G>T p.E2236* (on ENST00000411767 / NM_080683.3; = p.E2217* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100363806; called by muse, mutect2, varscan2
- PTPRG | c.2647A>G p.I883V | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99872177; called by muse, mutect2, varscan2
- RBM15 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.045); catalogued as COSV100873373; called by muse, mutect2, varscan2
- RHO | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as rs1251088622, COSV56212876, COSV99960439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHPN1 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 42/67 reads (63%) | catalogued as COSV100000318; called by muse, mutect2, varscan2
- RNF165 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.378); catalogued as COSV53970939, COSV99491142; called by muse, mutect2, varscan2
- ROCK1 | c.3154G>T p.V1052L | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV101296200; called by muse, mutect2, varscan2
- RPAP3 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs1391274800, COSV50043214, COSV99139240; called by muse, mutect2, varscan2
- RPIA | c.525C>T p.G175= | Splice Region (SNP) | VAF 36/83 reads (43%) | catalogued as rs369259154; called by muse, mutect2, varscan2
- RUNX1T1 | c.1408G>C p.E470Q (on ENST00000265814 / NM_001198628.1; = p.E443Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.709); catalogued as COSV99748333; called by muse, mutect2, varscan2
- SAFB2 | c.2440C>T p.H814Y | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99385251; called by muse, mutect2
- SAFB2 | c.2438G>T p.R813L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV99385252; called by muse, mutect2
- SBF2 | c.2338G>A p.G780R | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as rs775404093, COSV99812613; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCRIB | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 16/25 reads (64%) | catalogued as COSV100252225; called by muse, mutect2, varscan2
- SGIP1 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.337); catalogued as COSV99389986; called by muse, mutect2, varscan2
- SLC4A11 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 85/192 reads (44%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV101195859; called by muse, mutect2, varscan2
- SLC7A14 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs146405741, COSV51587290; called by muse, mutect2, varscan2
- SNRNP200 | c.1352A>T p.K451M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100106830; called by muse, mutect2, varscan2
- SPAST | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV100188196; called by muse, mutect2, varscan2
- SPATA17 | c.965A>G p.Q322R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100860852; called by muse, mutect2, varscan2
- ST18 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99387607; called by muse, mutect2, varscan2
- SUMF1 | c.17T>A p.L6Q | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.055); catalogued as COSV99794335; called by muse, mutect2, varscan2
- SUPT3H | c.569C>T p.S190L (on ENST00000371460 / NM_181356.3; = p.S179L on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs552055325, COSV100175800; called by muse, mutect2, varscan2
- TBC1D26 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs1392549850, COSV101343596; called by muse, mutect2, varscan2
- TDRD5 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV99675114; called by muse, mutect2
- TESK1 | c.1304G>A p.C435Y | Missense Mutation (SNP) | VAF 122/194 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99427218; called by muse, varscan2
- TMEM131 | c.2870G>A p.R957K | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99486072; called by muse, mutect2, varscan2
- TMEM50A | c.67A>G p.I23V | Missense Mutation (SNP) | VAF 55/72 reads (76%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV100975888; called by muse, mutect2, varscan2
- TNFSF13B | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101022302; called by muse, mutect2, varscan2
- TNR | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 118/222 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766116033, COSV54898964, COSV99686717; called by muse, mutect2, varscan2
- TPX2 | c.782A>T p.H261L | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100301409; called by muse, mutect2, varscan2
- TRIL | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1243299134, COSV100538633; called by muse, mutect2, varscan2
- TRIM50 | c.633G>T p.Q211H | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100296713; called by muse, mutect2
- TRPM1 | c.3856G>T p.D1286Y | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV99855105; called by muse, mutect2, varscan2
- TTN | c.54671C>A p.S18224* (on ENST00000591111; = p.S10800* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 32/167 reads (19%) | catalogued as COSV60292844; called by muse, mutect2, varscan2
- TTN | c.50669C>T p.P16890L (on ENST00000591111; = p.P9466L on NM_003319.4) | Missense Mutation (SNP) | VAF 28/59 reads (47%) | PolyPhen benign (0.083); catalogued as COSV59986004; called by muse, mutect2, varscan2
- UBE2E3 | c.505del p.L169Ffs*2 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | catalogued as COSV66585585; called by mutect2, pindel, varscan2
- USP46 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs1448129779, COSV71512755; called by muse, mutect2
- VAT1L | c.535C>G p.R179G | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV100212750; called by muse, varscan2
- VAV2 | c.2388G>T p.Q796H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV100895452, COSV100896000; called by muse, mutect2, varscan2
- XIAP | c.99T>A p.F33L | Missense Mutation (SNP) | VAF 64/76 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848803; called by muse, mutect2, varscan2
- XIRP2 | c.1654G>A p.G552R (on ENST00000628543; = p.G727R on NM_152381.6) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99736640, COSV99741871; called by muse, mutect2, varscan2
- XKR9 | c.607A>G p.I203V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101281794; called by muse, mutect2, varscan2
- XYLB | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as COSV99263844; called by muse, mutect2, varscan2
- ZFAT | c.3182A>G p.K1061R | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1298069094, COSV100914067; called by muse, mutect2, varscan2
- ZFHX4 | c.10249G>A p.A3417T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.743); catalogued as rs376071984; called by muse, mutect2, varscan2
- ZFR | c.2198C>A p.T733N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV99415151; called by muse, mutect2, varscan2
- ZNF214 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99547048; called by muse, mutect2
- ZNF254 | c.570A>T p.L190F | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100741444; called by muse, mutect2, varscan2
- ZNF311 | c.1675G>T p.V559L | Missense Mutation (SNP) | VAF 69/91 reads (76%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as COSV101014049; called by muse, mutect2, varscan2
- ZNF319 | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99539896; called by muse, mutect2, varscan2
- ZNF48 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV100197981, COSV100198174; called by muse, mutect2, varscan2
- ZNF559 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568369092, COSV100416347, COSV57835296; called by muse, mutect2, varscan2
- ZNF564 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100212932; called by muse, mutect2
- ZNF763 | c.106A>G p.T36A (on ENST00000358987 / NM_001367172.2; = p.T39A on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs549909286, COSV100675893; called by muse, mutect2, varscan2
- BARHL1 | c.515dup p.V173Gfs*60 | Frame Shift Ins (INS) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- CASD1 | c.328del p.Q110Nfs*35 | Frame Shift Del (DEL) | VAF 63/202 reads (31%) | called by mutect2, pindel, varscan2
- IGHV1-24 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- LILRB3 | c.861C>A p.S287R | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.33); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- NSD1 | c.6413del p.C2138Sfs*12 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | called by mutect2, pindel, varscan2
- OR52B2 | c.392del p.P131Hfs*2 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- PLD2 | c.861-9_861-2del p.X287_splice | Splice Site (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel
- SPARC | c.461del p.P154Lfs*7 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.2008C>G p.H670D | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBC1D2 | c.556del p.T186Hfs*5 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- TMEM236 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 47/400 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM33 | c.1470C>A p.G490= | Silent (SNP) | VAF 49/153 reads (32%) | catalogued as COSV100597627; called by muse, mutect2, varscan2
- ADAMTS12 | c.36T>C p.L12= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV100710036; called by muse, mutect2, varscan2
- AHNAK2 | c.7311G>C p.V2437= | Silent (SNP) | VAF 77/274 reads (28%) | catalogued as COSV100314888; called by muse, mutect2, varscan2
- BPIFB4 | c.1419G>A p.E473= | Silent (SNP) | VAF 89/269 reads (33%) | catalogued as COSV100971374; called by muse, mutect2, varscan2
- BRMS1L | c.741G>T p.L247= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs753054401, COSV99396441; called by muse, mutect2, varscan2
- CABP2 | c.513C>A p.R171= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV99590665; called by muse, mutect2, varscan2
- CASKIN1 | c.3537C>A p.R1179= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100398914; called by muse, mutect2, varscan2
- CHN1 | c.846A>G p.P282= | Silent (SNP) | VAF 84/195 reads (43%) | catalogued as COSV55034382; called by muse, mutect2, varscan2
- CHRM2 | c.510T>A p.T170= | Silent (SNP) | VAF 76/187 reads (41%) | catalogued as COSV100280430; called by muse, mutect2, varscan2
- CLDN23 | c.25C>T p.L9= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV101093006; called by muse, mutect2, varscan2
- CNIH2 | c.144G>T p.A48= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV100268249; called by muse, mutect2, varscan2
- DIP2A | c.2541G>C p.V847= | Silent (SNP) | VAF 49/239 reads (21%) | catalogued as COSV100594961; called by muse, mutect2, varscan2
- DNAH5 | c.10657C>A p.R3553= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV54218517, COSV99443101; called by muse, mutect2, varscan2
- DNAH5 | c.10656C>G p.A3552= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV99443103; called by muse, mutect2, varscan2
- DNAH5 | c.6885G>C p.A2295= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV54242772, COSV99443106; called by muse, mutect2, varscan2
- DNAH6 | c.2418G>A p.V806= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV99403988; called by muse, mutect2, varscan2
- DSG4 | c.1803G>A p.A601= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs748792251, COSV57396653, COSV57398034; called by muse, mutect2, varscan2
- ECPAS | c.4053C>T p.G1351= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as rs764441380, COSV52205183; called by muse, mutect2
- EPS8L2 | c.444G>A p.P148= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs372636952, COSV100585430; called by muse, mutect2, varscan2
- FBXO15 | c.870G>T p.R290= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV99502892; called by muse, mutect2, varscan2
- FCRLA | c.282C>T p.F94= (on ENST00000367959; = p.F71= on NM_032738.4) | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99375569; called by muse, mutect2, varscan2
- FHOD3 | c.2470A>C p.R824= (on ENST00000359247 / NM_001281739.3; = p.R841= on NM_025135.5) | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99939580; called by muse, mutect2, varscan2
- FMR1NB | c.528A>G p.P176= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100789518; called by muse, mutect2, varscan2
- FRY | c.2862C>T p.Y954= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs535359859, COSV100968651; called by muse, mutect2, varscan2
- GAS2L2 | c.1773C>G p.P591= | Silent (SNP) | VAF 54/114 reads (47%) | called by muse, mutect2, varscan2
- GRIP1 | c.684A>G p.Q228= | Silent (SNP) | VAF 96/246 reads (39%) | catalogued as COSV99667453; called by muse, mutect2, varscan2
- IAH1 | c.165A>C p.S55= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs747931342, COSV100697046; called by muse, mutect2, varscan2
- IGHA1 | c.579C>A p.A193= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- INHBA | c.768C>A p.L256= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99636940; called by muse, mutect2, varscan2
- IPO9 | c.2487A>G p.G829= | Silent (SNP) | VAF 55/136 reads (40%) | catalogued as rs778982225, COSV100843266; called by muse, mutect2, varscan2
- IRF7 | c.1089G>A p.L363= (on ENST00000397566; = p.L350= on NM_001572.5) | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as rs1188984179, COSV99199336; called by muse, mutect2
- ITIH2 | c.795G>T p.R265= | Silent (SNP) | VAF 75/172 reads (44%) | catalogued as COSV100623103; called by muse, mutect2, varscan2
- KIF2B | c.900T>C p.F300= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV99274423; called by muse, mutect2, varscan2
- MATK | c.69C>A p.P23= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV100035744; called by muse, mutect2, varscan2
- MYH8 | c.3426C>T p.L1142= | Silent (SNP) | VAF 65/116 reads (56%) | catalogued as COSV101238034; called by muse, mutect2, varscan2
- NELL2 | c.591G>C p.A197= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs373223141, COSV100418349; called by muse, mutect2, varscan2
- NETO1 | c.1014G>T p.L338= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV100197967; called by muse, mutect2, varscan2
- NMUR2 | c.966C>A p.V322= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV99676485, COSV99676940; called by muse, mutect2, varscan2
- NUP160 | c.2949T>A p.A983= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV101021163; called by muse, mutect2, varscan2
- NUP210 | c.2247G>A p.P749= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs768612746, COSV99595297; called by muse, mutect2, varscan2
- OR2M2 | c.768G>A p.L256= | Silent (SNP) | VAF 136/356 reads (38%) | catalogued as COSV100677128; called by muse, varscan2
- PDE4DIP | c.4134G>T p.R1378= | Silent (SNP) | VAF 33/161 reads (20%) | catalogued as rs781829206, COSV57702960; called by muse, mutect2, varscan2
- PLPP7 | c.738C>T p.I246= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs369163929; called by muse, mutect2, varscan2
- PLPPR2 | c.444G>A p.Q148= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV99264133; called by muse, mutect2, varscan2
- PROCA1 | c.1035A>C p.S345= (on ENST00000439862 / NM_001366301.1; = p.S317= on NM_152465.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/356 reads (4%) | catalogued as COSV99972450; called by muse, mutect2
- PTPRO | c.18G>A p.T6= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV99839268; called by muse, mutect2, varscan2
- SLC1A6 | c.894C>T p.S298= | Silent (SNP) | VAF 90/170 reads (53%) | catalogued as COSV99693272; called by muse, mutect2, varscan2
- SLC27A6 | c.1851A>C p.I617= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as COSV99321922; called by muse, mutect2, varscan2
- SPATA31D1 | c.1368C>G p.T456= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs1328956526, COSV100782381; called by muse, mutect2, varscan2
- STEAP1 | c.894A>G p.P298= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as COSV99787462; called by muse, mutect2
- SYNE2 | c.18600C>T p.Y6200= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs1260329493, COSV100646333; called by muse, mutect2, varscan2
- TBX22 | c.1029C>T p.C343= | Silent (SNP) | VAF 36/55 reads (65%) | catalogued as COSV100960549; called by muse, mutect2, varscan2
- THBS1 | c.2316C>T p.D772= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as COSV99527396, COSV99528262; called by muse, mutect2, varscan2
- TMEM230 | c.246G>T p.V82= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV99176935; called by muse, mutect2
- TMEM26 | c.894G>A p.V298= | Silent (SNP) | VAF 53/79 reads (67%) | catalogued as COSV99515364; called by muse, mutect2, varscan2
- TPH2 | c.279T>C p.H93= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs562686847, COSV100421785; called by muse, mutect2, varscan2
- TRHDE | c.1716G>A p.S572= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs781517261, COSV53856134; called by muse, mutect2, varscan2
- TTN | c.9258C>A p.I3086= (on ENST00000591111; = p.I3040= on NM_003319.4) | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV100588412; called by muse, mutect2, varscan2
- UBE3C | c.882C>T p.Y294= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as rs758736337, COSV100779615; called by muse, mutect2, varscan2
- UBR4 | c.12582G>A p.A4194= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs751766331, COSV100919864; called by muse, mutect2, varscan2
- ZFHX4 | c.8046C>A p.A2682= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV50520254; called by muse, mutect2, varscan2
- ZIC1 | c.1161C>T p.S387= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs1047106709, COSV99291308; called by muse, mutect2, varscan2
- ZNF804A | c.2415C>T p.P805= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100165679, COSV56439927; called by muse, mutect2, varscan2
- BRD2 | c.-2A>C | 5'UTR (SNP) | VAF 27/113 reads (24%) | catalogued as COSV100875521; called by muse, mutect2, varscan2
- CFAP47 | c.2844+64G>A | Intron (SNP) | VAF 22/36 reads (61%) | catalogued as COSV99934021; called by muse, mutect2, varscan2
- DPP6 | c.627+21129C>G | Intron (SNP) | VAF 71/232 reads (31%) | catalogued as COSV100122334, COSV100123846; called by muse, mutect2, varscan2
- KCNK10 | c.38-7189C>T | Intron (SNP) | VAF 34/448 reads (8%) | catalogued as rs1248305761, COSV100066915; called by muse, mutect2
- MIR147A | n.24C>A | RNA (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- SSPOP | n.4542T>C | RNA (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100021985; called by muse, mutect2, varscan2
- TTN | c.10360+4797T>A | Intron (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100588408, COSV60087917; called by muse, mutect2, varscan2
- TTN | c.10360+4198G>T | Intron (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100588409; called by muse, mutect2, varscan2
- UBAC2 | c.808-11566A>C | Intron (SNP) | VAF 108/334 reads (32%) | catalogued as COSV63121979; called by muse, mutect2, varscan2
- UBTFL2 | n.811C>T | RNA (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
